Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3U9, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3U9-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
CC:
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
[REDACTED]

Specimens Submitted:
1: SP: Perirectal leiomyosarcoma

DIAGNOSIS:

- 1) SOFT TISSUE, PERIRECTAL, EXCISION:
- HIGH GRADE LEIOMYOSARCOMA, 6.4 CM GREATEST DIMENSION, INVADING FIBROADIPOSE TISSUE AND ABUTTING SKELETAL AND SMOOTH MUSCLE.
- IMMUNOSTAINS ARE POSITIVE FOR SMA AND DESMIN, NEGATIVE FOR CD117 AND CALDESMON.
- TUMOR EXTENDS TO UNDESIGNATED INKED MARGINS AT MULTIPLE FOCI.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:		
Result	Special Stain	Comment
	CMA (HHF35)	
	des	
	Caldesmon	
	CD117	
	NEG CONT	
	IMM RECUT	

Gross Description:

- 1) The specimen is received fresh, labeled "Perirectal leiomyosarcoma"

** Continued on next page **

ICD-0-3

leiomyosarcoma, NOS 8890/3

Path site: perirectal region, NOS C76.3

cQcF: Retroperitoneum C48.0

fw
9/11/12

[page 2 of 2]
SURGICAL

----- Page 2 of 2
and consists of an irregularly shaped, unoriented piece of yellow-tan lobulated soft to rubbery tissue measuring 13.2 x 6.6 x 3.7 cm. One surface is slightly smoother. The margins are inked in black. At one end of the specimen, a well-circumscribed white tan whorled nodular mass is identified measuring 6.4 to 5.5 x 3.6 cm, focally abutting the inked margins. Foci are identified where a thin transparent membrane is noted. Foci of red-tan skeletal muscle are identified. Cut section through the nodule reveals a white-tan homogenous whorled glistening cut surface, with areas of hemorrhage and glistening tan myxoid areas noted. The nodule appears entirely viable. Serial sections through the tissue reveals areas of indurated white-tan tissue abutting skeletal muscle, showing possible areas of infiltration, focally abutting the inked margin. Sections through the remaining tissue reveal yellow tan lobulated focally hemorrhagic soft tissue and areas of red-tan skeletal muscle. Representative sections of the specimen are submitted to TPS, and for permanent section. Photographs have been taken.

Summary of sections:
RS- representative section

Summary of Sections:
Part 1: SP: Perirectal leiomyosarcoma

Block	Sect.	Site	PCs
13		rs	13

** End of Report **

HIFAA Discrepancy		
Dual/Synchronous Primary M.T. ed		

Source: NCI Genomic Data Commons file c641f220-fae3-43d7-b7d5-9c5dd279baf9 (TCGA-DX-A3U9.C04B97F6-B2D2-4EF3-BE23-141A7640D577.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).